Gene-level copy-number profile of tumor specimen TCGA-PT-A8TR-01A from TCGA case TCGA-PT-A8TR, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxoid leiomyosarcoma; Tissue or organ of origin: Isthmus uteri; Age at diagnosis: 57.5 years (20,985 days).
Specimen TCGA-PT-A8TR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.927b221d-3897-419f-a4e9-43490b8ebe73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PT-A8TR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate.
https://portal.gdc.cancer.gov/files/6fa53e67-0b49-45ac-b61c-21c17000ea4a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,283; copy number 2: 50,786; copy number 3: 3,425; copy number 4: 3,324.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:46,193,576–46,196,723, 1 gene: KANSL1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
